Somatic mutation profile of cancer-model specimen HCM-BROD-0055-C64-85A (2D Modified Conditionally Reprogrammed Cells, passage 13; aliquot HCM-BROD-0055-C64-85A-01D-A79L-36), derived from the primary tumor of HCMI case HCM-BROD-0055-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 0.4 years (162 days).
Specimen HCM-BROD-0055-C64-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 13.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 062c52ba-6f2e-4769-9a75-ce13ce52403c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0055-C64-11A (Solid Tissue Normal), aliquot HCM-BROD-0055-C64-11A-11D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/914755fd-85f6-42c7-a763-3b6a10ef0ed4

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.13192G>T p.G4398C | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAREM1 | c.435C>G p.N145K | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SNAP91 | c.2661G>C p.Q887H | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SNRNP200 | c.1019A>C p.E340A | Missense Mutation (SNP) | VAF 55/323 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SP4 | c.1880G>T p.C627F | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TCEAL6 | c.354G>A p.T118= | Silent (SNP) | VAF 12/346 reads (3%) | called by muse, mutect2
